Somatic mutation profile of tumor specimen MP2PRT-PASLFB-TMP1-A (aliquot MP2PRT-PASLFB-TMP1-A-1-0-D-A82A-36) from MP2PRT case MP2PRT-PASLFB, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 16.4 years (6,003 days).
Specimen MP2PRT-PASLFB-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e42b3a9b-6510-4cea-9498-72c079255ff8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PASLFB-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PASLFB-NB1-A-1-0-D-A82A-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/30bdd1c6-ea1d-451c-bfe5-b7fcf5e8a246

The open-access MAF lists 22 somatic variants for this specimen: 17 protein-altering or splice-affecting, 4 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 11, Silent 4, Nonsense Mutation 2, Splice Site 2, Frame Shift Ins 1, Frame Shift Del 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>C p.G12A | Missense Mutation (SNP) | VAF 92/273 reads (34%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen possibly damaging (0.723); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- AKT1S1 | c.67C>T p.R23W (on ENST00000344175 / NM_001098633.4; = p.R43W on NM_032375.5) | Missense Mutation (SNP) | VAF 336/835 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.453); catalogued as rs1335300230; called by muse, mutect2, varscan2
- CD1E | c.316C>T p.Q106* | Nonsense Mutation (SNP) | VAF 89/230 reads (39%) | catalogued as rs770576446, COSV63770265, COSV63773170; called by muse, mutect2, varscan2
- FAM50A | c.859G>A p.D287N | Missense Mutation (SNP) | VAF 190/505 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1557200364, COSV50131047; called by muse, mutect2, varscan2
- GAD2 | c.1339G>A p.G447R | Missense Mutation (SNP) | VAF 74/373 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs376780859, COSV52156232; called by muse, mutect2, varscan2
- KCNU1 | c.605G>A p.R202H | Missense Mutation (SNP) | VAF 87/246 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs180964986, COSV67755904; called by muse, mutect2, varscan2
- MYH2 | c.508C>T p.R170* | Nonsense Mutation (SNP) | VAF 26/123 reads (21%) | catalogued as rs750232956; called by muse, mutect2, varscan2
- OR2L8 | c.736G>A p.V246I | Missense Mutation (SNP) | VAF 76/233 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.247); catalogued as rs371086314, COSV100594327; called by muse, mutect2, varscan2
- SALL1 | c.1199C>T p.S400L | Missense Mutation (SNP) | VAF 157/430 reads (37%) | SIFT tolerated (0.08); PolyPhen benign (0.009); catalogued as rs200089484, COSV51760413; called by muse, mutect2, varscan2
- CENPJ | c.13C>A p.P5T | Missense Mutation (SNP) | VAF 80/220 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.17); called by muse, mutect2, varscan2
- ETV6 | c.1179_1180insG p.M394Dfs*32 | Frame Shift Ins (INS) | VAF 99/332 reads (30%) | called by mutect2, pindel*, varscan2*
- GUCY2C | c.1820G>T p.S607I | Missense Mutation (SNP) | VAF 111/306 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- KMT2D | c.1483_1486del p.S495Rfs*434 | Frame Shift Del (DEL) | VAF 190/575 reads (33%) | called by mutect2, pindel, varscan2
- OR5AK2 | c.820G>T p.A274S | Missense Mutation (SNP) | VAF 46/122 reads (38%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.718); called by muse, mutect2, varscan2
- THBS1 | c.1835A>T p.D612V | Missense Mutation (SNP) | VAF 171/423 reads (40%) | SIFT tolerated (0.36); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TMEM191B | c.451_471+5delinsCTT p.X151_splice | Splice Site (DEL) | VAF 27/132 reads (20%) | called by pindel, varscan2*
- TMEM191C | c.451_471+5delinsCTT p.X151_splice | Splice Site (DEL) | VAF 72/330 reads (22%) | called by pindel, varscan2*
- MYO9B | c.174C>T p.D58= | Silent (SNP) | VAF 168/453 reads (37%) | catalogued as rs374279682; called by muse, mutect2, varscan2
- PCDHA11 | c.2250G>A p.S750= | Silent (SNP) | VAF 194/508 reads (38%) | catalogued as rs374659815; called by muse, mutect2, varscan2
- RTEL1 | c.2901C>A p.V967= | Silent (SNP) | VAF 136/375 reads (36%) | called by muse, mutect2, varscan2
- USP49 | c.669C>T p.A223= | Silent (SNP) | VAF 250/1008 reads (25%) | called by muse, varscan2
- IGHV3-53 | chr14:106592675 ins TCTCCCTGGC | 3'Flank (INS) | VAF 32/150 reads (21%) | called by pindel, varscan2
